Somatic mutation profile of tumor specimen TCGA-2G-AAG8-01A (aliquot TCGA-2G-AAG8-01A-31D-A42Y-10) from TCGA case TCGA-2G-AAG8, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 21.0 years (7,688 days).
Specimen TCGA-2G-AAG8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d3f76fb-18fa-4967-892e-aa83382b9ec8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAG8-10A (Blood Derived Normal), aliquot TCGA-2G-AAG8-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50b181e6-9b0d-4e6b-bdb0-8dd8085770da

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 3, Silent 3, Splice Site 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYTH3 | c.1124C>G p.S375C (on ENST00000396741; = p.S374C on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as COSV60364363; called by muse, mutect2, varscan2
- IFRD1 | c.1280_1281del p.S427Cfs*10 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs1309045147; called by pindel, varscan2
- RAPGEF6 | c.2467C>A p.Q823K | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV57240598; called by muse, mutect2
- ATG4B | c.1014+1G>T p.X338_splice | Splice Site (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- BEST2 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPN7 | c.1489T>C p.W497R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GMEB1 | c.219A>G p.I73M | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.328); called by muse, mutect2
- H4C7 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2
- HSPA5 | c.1792G>A p.V598I | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PDE10A | c.1306T>G p.C436G | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RPRD2 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); called by muse, mutect2
- SLC35F3 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TBC1D32 | c.2163C>A p.S721R | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- ZP2 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ABCA2 | c.5658C>T p.V1886= (on ENST00000614293; = p.V1856= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- KNL1 | c.5808A>G p.Q1936= (on ENST00000346991 / NM_170589.5; = p.Q1910= on NM_144508.5) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs748300152; called by muse, mutect2, varscan2
- LRP4 | c.3483G>A p.L1161= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.1588-49C>A | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- GON4L | c.1788+101T>C | Intron (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- LEXM | c.1185-119C>T | Intron (SNP) | VAF 29/92 reads (32%) | catalogued as rs368328187; called by muse, mutect2, varscan2
- TRMT5 | c.*1T>C | 3'UTR (SNP) | VAF 19/226 reads (8%) | called by muse, mutect2
